Somatic mutation profile of tumor specimen TCGA-E1-A7YD-01A (aliquot TCGA-E1-A7YD-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 57.5 years (21,020 days).
Specimen TCGA-E1-A7YD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e4aaefb-253b-4d39-b25d-9714d9608e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YD-10A (Blood Derived Normal), aliquot TCGA-E1-A7YD-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32708ab1-d0d7-437a-a7aa-3b93b5d4237b

The open-access MAF lists 62 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 15, Nonsense Mutation 2, 5'UTR 2, Splice Site 1, Translation Start Site 1, Frame Shift Del 1, RNA 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs762387914, CM940127, COSV61689665; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.1672A>G p.K558E | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057520031, COSV55391106, COSV55395581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 51/59 reads (86%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ABCA5 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67017286; called by muse, mutect2, varscan2
- AFF4 | c.3482T>A p.L1161* | Nonsense Mutation (SNP) | VAF 58/132 reads (44%) | catalogued as COSV99534800; called by muse, mutect2, varscan2
- CHPF2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99223001; called by muse, mutect2, varscan2
- CHRNA4 | c.1597T>C p.C533R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV64719901; called by muse, mutect2
- COL6A3 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369379463, COSV55093992; called by muse, mutect2, varscan2
- COX10 | c.149T>G p.F50C | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.619); catalogued as COSV99886265; called by muse, mutect2, varscan2
- CST4 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs138934020, COSV54149617; called by muse, mutect2, varscan2
- CYLC1 | c.1886T>C p.M629T | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV61412965; called by muse, mutect2, varscan2
- DNASE2B | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101042071; called by muse, mutect2, varscan2
- EGFR | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 508/550 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV51785554, COSV51829933; called by mutect2, varscan2
- ETNPPL | c.316_319del p.C106Ifs*12 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs753551149; called by pindel, varscan2
- FARP2 | c.3145G>C p.V1049L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV99884360; called by muse, mutect2, varscan2
- FLG | c.2671A>C p.S891R | Missense Mutation (SNP) | VAF 130/665 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1476265194, COSV100910462, COSV64239905; called by muse, mutect2, varscan2
- FZD9 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782493264, COSV60669452; called by muse, mutect2, varscan2
- GSTA2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as rs750745710, COSV101534039; called by muse, mutect2, varscan2
- HNRNPF | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as rs1457498637, COSV61561897; called by muse, mutect2, varscan2
- IGF2R | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV63628570; called by muse, mutect2, varscan2
- IPO13 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV64894564; called by muse, mutect2, varscan2
- IQCF2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs140755124; called by muse, mutect2, varscan2
- LAMA2 | c.8765T>A p.L2922Q | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.692); catalogued as COSV101370336; called by muse, mutect2, varscan2
- LAPTM5 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99612342; called by muse, mutect2, varscan2
- LRP1B | c.2659C>G p.P887A | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV63341793; called by muse, mutect2
- MRGPRX1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs1309719773, COSV57107643; called by muse, mutect2, varscan2
- NOS1 | c.2617T>C p.F873L | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV57614749; called by muse, mutect2, varscan2
- OR10R2 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1427918025, COSV100936778; called by muse, mutect2, varscan2
- OR1N2 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV65460819; called by muse, mutect2, varscan2
- PCLO | c.9629A>T p.Q3210L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV61642172; called by muse, mutect2, varscan2
- PDGFRB | c.734T>G p.F245C | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55806265, COSV55809736; called by muse, mutect2, varscan2
- PIK3CA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 35/49 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55935970; called by muse, mutect2, varscan2
- PRAMEF19 | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 243/687 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs765510606; called by muse, mutect2, varscan2
- PSME1 | c.246G>A p.E82= | Splice Region (SNP) | VAF 30/39 reads (77%) | catalogued as rs1209461998, COSV99246147; called by muse, mutect2, varscan2
- RYR2 | c.4498C>T p.R1500C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs778394498, COSV63680185; called by muse, mutect2, varscan2
- SAFB2 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV99385593, COSV99386070; called by muse, mutect2, varscan2
- SEMG1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); catalogued as rs199781597; called by muse, mutect2, varscan2
- SNTG2 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.588); catalogued as rs760366173, COSV57969669, COSV57975654; called by muse, mutect2
- TMCO4 | c.877+1G>A p.X293_splice | Splice Site (SNP) | VAF 34/143 reads (24%) | catalogued as rs145825608, COSV53873802; called by muse, mutect2, varscan2
- TMTC2 | c.2495A>G p.K832R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1473449094, COSV58272447; called by muse, mutect2, varscan2
- TRIM69 | c.704A>G p.E235G (on ENST00000329464 / NM_182985.5; = p.E76G on NM_080745.5) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100274227; called by muse, mutect2
- VSTM2L | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 94/178 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65096098; called by muse, mutect2, varscan2
- ZPBP | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV50423332; called by muse, mutect2, varscan2
- ZNF416 | c.1033dup p.C345Lfs*11 | Frame Shift Ins (INS) | VAF 23/101 reads (23%) | called by mutect2, pindel, varscan2
- AC092143.1 | c.1803C>T p.A601= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs758044135, COSV59247294; called by muse, mutect2, varscan2
- BRAT1 | c.837G>C p.L279= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100500423; called by muse, mutect2, varscan2
- CDC42BPG | c.1746G>A p.S582= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs375810376; called by muse, mutect2, varscan2
- CNGB3 | c.357T>C p.P119= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as COSV100181685; called by muse, mutect2, varscan2
- DAAM2 | c.240C>A p.I80= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99225289; called by muse, mutect2
- E2F3 | c.1003C>T p.L335= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100685905; called by muse, mutect2, varscan2
- FGF22 | c.381C>T p.Y127= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs751825478, COSV99293693; called by muse, mutect2, varscan2
- ITGAX | c.3009C>T p.I1003= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs371222071; called by muse, mutect2, varscan2
- ITGB2 | c.714C>T p.D238= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs752901414, COSV56608073; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- KCNK18 | c.648A>C p.T216= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV100572020; called by muse, mutect2, varscan2
- MMP1 | c.786T>A p.R262= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV100187888; called by muse, mutect2, varscan2
- OLFML2A | c.837C>T p.R279= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs374490177; called by muse, mutect2, varscan2
- QRICH2 | c.3177C>T p.T1059= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as rs746553412, COSV99429003; called by muse, mutect2, varscan2
- TUBB6 | c.258G>T p.R86= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100481007; called by muse, mutect2, varscan2
- XDH | c.2250C>T p.T750= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV101052150; called by muse, mutect2, varscan2
- GLYATL1 | c.-119A>T | 5'UTR (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100265252; called by muse, mutect2
- RNF17 | c.-2C>T | 5'UTR (SNP) | VAF 18/54 reads (33%) | catalogued as rs776859084, COSV55042520; called by muse, mutect2, varscan2
- STAG3L4 | n.622A>T | RNA (SNP) | VAF 82/254 reads (32%) | called by muse, mutect2, varscan2
